CPTAC case SC-0240 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b6004c9c-c3c9-4ff5-a37b-169120ca65ba

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of lower limb and hip; Age at diagnosis: 59.0 years (21,550 days); AJCC staging edition: 8th; AJCC pathologic T: T4b; AJCC pathologic N: N1a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Progression or recurrence: no; Days to last follow up: 1,613 days (4.4 years); Clark level: V.
   Pathology details: Breslow thickness: 16.

Biospecimens (2 samples)
- Sample S-1710-009480: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 174 mg; Method of sample procurement: Tumor Resection.
- Sample S-1710-009481: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 200 mg; Method of sample procurement: Tumor Resection.
